Somatic mutation profile of tumor specimen 0DESUD from CCDI case PBBPXX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, biphasic; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 13.7 years (5,006 days).
Specimen 0DESUD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d2618f7-4027-45ce-bcfa-2a414d96f627.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DESUQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e00260ee-91cb-4a9b-b933-be41cc211333

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-4 | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 304/643 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV64210916; called by muse, mutect2, varscan2
- HECTD1 | c.7111C>T p.R2371C | Missense Mutation (SNP) | VAF 275/574 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs374624832; called by muse, mutect2, varscan2
- ITGA10 | c.1139A>G p.H380R | Missense Mutation (SNP) | VAF 247/540 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782358265; called by muse, mutect2, varscan2
- RBP3 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1419192934; called by muse, mutect2
- NRCAM | c.1836G>A p.G612= (on ENST00000379028 / NM_001371124.1; = p.G606= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 22/806 reads (3%) | called by muse, mutect2
- PADI4 | c.882G>A p.A294= | Silent (SNP) | VAF 261/532 reads (49%) | catalogued as rs765222511, COSV64923081; called by muse, mutect2, varscan2
